Gene-level copy-number profile of specimen HCM-WCMC-0788-C34-85A from HCMI case HCM-WCMC-0788-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.6 years (26,516 days).
Specimen HCM-WCMC-0788-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a6c74e9f-cd59-4708-8b7f-9cf86d1ba8d7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0788-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/3e455577-a4e7-4aa7-a51a-5482a13fecd6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 823; copy number 2: 2,638; copy number 3: 16,029; copy number 4: 17,700; copy number 5: 14,397; copy number 6: 2,840; copy number 7: 2,488; copy number 8: 1,139; copy number 9: 178; copy number 10: 264; copy number 11: 350; copy number 12: 13; copy number 13: 29; copy number 15: 3.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 837 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,902,980–169,904,260, 1 gene, copy number 9: KRT18P43.
- chr5:441,498–535,882, 7 genes, copy number 9: EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456.
- chr5:767,382–1,728,172, 34 genes, copy number 9–11: BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1.
- chr5:3,177,835–3,181,487, 1 gene, copy number 9: LINC01377.
- chr5:8,717,684–8,717,883, 1 gene, copy number 9: AC091932.4.
- chr5:37,811,589–45,895,970, 120 genes, copy number 10–15 (broad region; genes not listed).
- chr6:28,503,296–31,817,946, 271 genes, copy number 9–12 (broad region; genes not listed).
- chr6:52,361,421–58,438,364, 106 genes, copy number 9–11 (broad region; genes not listed).
- chr7:56,567,906–56,650,696, 6 genes, copy number 10–13: AC092447.2, AC092447.6, AC092447.1, AC092447.9, TRIM60P16, AC095038.1.
- chr7:62,275,361–63,176,019, 8 genes, copy number 9: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1.
- chr8:74,234,700–75,566,834, 21 genes, copy number 10: JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G.
- chr8:80,034,745–80,874,781, 26 genes, copy number 9–10 (within-gene range 7–10): TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41.
- chr8:95,986,108–97,358,478, 19 genes, copy number 10: AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H.
- chr8:119,165,034–128,187,101, 153 genes, copy number 10–12 (within-gene range 7–12) (broad region; genes not listed).
- chr10:25,174,802–25,602,229, 1 gene, copy number 10 (within-gene range 7–10): GPR158.
- chr10:25,393,557–27,316,587, 36 genes, copy number 10: RN7SKP220, GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P, AL358612.1, MYO3A, GAD2, APBB1IP, RNA5SP307, AL160287.1, FAM238A, AL390961.1, FAM238B, SELENOOLP, AL390961.3, PDSS1, HSPA8P3, AL390961.2, ABI1, AL139404.1, RNU6-946P, FAM238C, ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P.
- chr15:85,255,369–85,330,334, 2 genes, copy number 10: ADAMTS7P4, AC044860.3.
- chr15:91,408,708–91,743,955, 5 genes, copy number 9–10: CRAT37, AC107958.3, AC107958.2, AC107958.1, THRAP3P2.
- chr15:97,560,849–97,875,650, 2 genes, copy number 9: AC026523.4, LINC00923.
- chr16:33,844,784–34,013,830, 15 genes, copy number 10: AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2.
- chr17:38,195,703–38,257,192, 2 genes, copy number 9: NPEPPSP1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 167. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
